Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7304, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7304-02A (Recurrent Tumor).

[page 1 of 3]
Anatomic Pathology/Cytology Document State: (version)

Update Date/Time:
Final

Patient Name: MRN: Service Date/Time:
DOB/Age/Gender: Male Provider:
Location: Responsible Staff:

Surgical Pathology Report
Patient Name: Accession #:
Med: Rec.: Phone Number:
DOB: (Age:) Gender: M
Client:
Taken:
Received:
Reported:
Physician(s):
Phy Location:

ICD-0-3 recurrence
oligoastrocytoma, anaplastic 9382/3
Site: cerebrum C71.0

hw
2/12/15

CLINICAL HISTORY

-year-old man had left atypical oligoastrocytoma operated on
, followed by XRT and Temodar. Current MRI demonstrates possible recurrent tumor.

OPERATIVE DIAGNOSES

Recurrent brain tumor.

Operation/Specimen: A: Brain, recurrent tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, site not specified, excision:

1. Mixed oligoastrocytoma, anaplastic.
2. MIB-1 proliferation index: \R\ 50%.

See Comment.

COMMENT

The specimen is portions of cerebrum extensively and heavily infiltrated by a glial neoplastic proliferation that has a mixed oligoastrocytic phenotype, predominantly astrocytic. The neoplastic cells have nuclear anaplastic features, and there is brisk mitotic activity. There is no appreciable microvascular cellular proliferation or necrosis.

The neoplasm has morphology similar to the original resection; in the current resection, however, there is distinct cellular anaplasia, with a very high proliferation index of about 50%.

LOH testing of the neoplasm is being performed, and result will be reported in an addendum.

Electronically Signed Out

, Senior Staff Pathologist
, Resident Pathologist

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Interpretation

POSITIVE: Allelic loss on chromosome arm 19q is detected.

There is no evidence of allelic loss on chromosome 1p.

[page 2 of 3]
Informative loci are: D1S548, D1S552, D19S219, D19S1182

Results-Comments

Test performed on paraffin block -A3 and peripheral blood for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

Electronically Signed Out

, Senior Staff Pathologist

=====

GROSS DESCRIPTION

SPECIMEN: Recurrent brain tumor.

FIXATIVE: Formalin.

GENERAL: Received are three irregular, pink-tan to gray-white fragments of brain tissue, ranging from .5 cm. in greatest dimension to 2.0 x 1.2 x 1.0 cm.

Two smaller fragments of brain tissue are bisected.

SECTIONS: All submitted; A1 - one fragment bisected, A2 - second fragment bisected, A3-A5 - largest fragment sectioned.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates tumor cells in a gliofibrillary background; many cells, however, appear as naked nuclei. A great majority of cells over express the p53 protein. With the MIB1 there is a proliferation index of about 50% in the denser white matter zones. The NeuN demonstrates the diffusely infiltrating character of the neoplasm.

ICD-9(s):

191.9 191.9

Billing Fee Code(s):

A:

LOH 1p19q:

Histo Data

Part A: Brain, recurrent tumor, excision biopsy

Taken: Received:

[page 3 of 3]
Stain/cnt Block Ordered Comment

H/E x 1 1

H/E x 1 2

mGFAP-DA x 1 3

H/E x 1 3

MIB1-DA x 1 3

NeuN x 1 3

P53DO7 x 1 3

H/E x 1 4

H/E x 1 5

*** End of Report ***

Source: NCI Genomic Data Commons file 52eec613-ba42-4f13-9f0c-c565075bb468 (TCGA-DU-7304.EFF2E68D-4795-413F-B5B1-EF9E5703A2B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).